Somatic mutation profile of tumor specimen TCGA-BP-5191-01A (aliquot TCGA-BP-5191-01A-01D-1429-08) from TCGA case TCGA-BP-5191, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 80.0 years (29,207 days).
Specimen TCGA-BP-5191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1463eb59-8518-494b-bf14-2bfc827111f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5191-11A (Solid Tissue Normal), aliquot TCGA-BP-5191-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2441fe1-0f3f-4cb5-8e43-d9272e9b0236

The open-access MAF lists 64 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 17, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 2, Splice Site 2, Frame Shift Del 2, RNA 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.8433G>T p.K2811N (on ENST00000359028; = p.K2787N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV62348529; called by muse, mutect2
- ANKRD2 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV53968479; called by muse, mutect2, varscan2
- CCDC146 | c.2063A>T p.E688V | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53549571; called by muse, mutect2, varscan2
- CCDC150 | c.66C>A p.N22K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as COSV55875128, COSV55876403; called by muse, mutect2, varscan2
- CLEC18B | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs1487124880, COSV60577744; called by muse, mutect2, varscan2
- CTBP1 | c.1048T>G p.C350G | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52074485; called by muse, mutect2, varscan2
- DGKQ | c.2722C>G p.P908A | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV53279295, COSV99297601; called by muse, mutect2, varscan2
- DKK1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 4/101 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV64760380; called by muse, mutect2
- EPAS1 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55387229; called by muse, mutect2, varscan2
- ERMARD | c.878T>A p.L293* | Nonsense Mutation (SNP) | VAF 25/190 reads (13%) | catalogued as COSV64648219; called by muse, mutect2, varscan2
- FAM222A | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV62723463; called by muse, mutect2, varscan2
- GLB1 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748345527, CM1210292, COSV56561435; called by muse, mutect2, varscan2
- IL23A | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV57336105; called by muse, mutect2, varscan2
- IL4R | c.2443G>T p.V815F | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV50146822; called by muse, mutect2, varscan2
- KAT14 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs765598660, COSV66607981; called by muse, mutect2
- KIF11 | c.1986G>C p.L662F | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.202); catalogued as COSV53271164; called by muse, mutect2, varscan2
- LIPI | c.1390A>G p.K464E | Missense Mutation (SNP) | VAF 84/282 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.043); catalogued as COSV60712257; called by muse, mutect2, varscan2
- LYST | c.7201T>G p.F2401V | Missense Mutation (SNP) | VAF 49/389 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV67707916; called by muse, mutect2, varscan2
- MTMR2 | c.1000G>C p.G334R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60580170; called by muse, mutect2
- NLRP6 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.413); catalogued as COSV56459924; called by muse, mutect2, varscan2
- NUTM2G | c.1433T>A p.L478H | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV63617372; called by muse, mutect2, varscan2
- PLXND1 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV60714627; called by muse, mutect2, varscan2
- PSENEN | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53075296; called by muse, mutect2, varscan2
- SALL4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs757354140, COSV53852998; called by muse, mutect2, varscan2
- SLC35B2 | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51489800; called by muse, mutect2, varscan2
- SPTB | c.2944G>C p.D982H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV67632526; called by muse, varscan2
- STAG2 | c.1907dup p.Y636* | Nonsense Mutation (INS) | VAF 44/93 reads (47%) | catalogued as COSV54350437; called by mutect2, pindel, varscan2
- TICAM1 | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV50233188; called by muse, mutect2, varscan2
- TRIOBP | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV100730807, COSV60378850; called by muse, mutect2, varscan2
- TRPM6 | c.841+1G>A p.X281_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as rs371363425; called by muse, mutect2, varscan2
- TTC7B | c.1664T>A p.L555H | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60632462; called by muse, mutect2, varscan2
- TTC8 | c.299+2T>C p.X100_splice (on ENST00000338104 / NM_001288781.1; = p.X110_splice on NM_144596.4) | Splice Site (SNP) | VAF 16/111 reads (14%) | catalogued as rs770087818, COSV57628179; called by muse, mutect2, varscan2
- UBIAD1 | c.816C>A p.F272L | Missense Mutation (SNP) | VAF 76/303 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV65147833; called by muse, mutect2, varscan2
- UNC13D | c.976T>G p.S326A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52885097; called by muse, mutect2, varscan2
- UPP2 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50047388; called by muse, mutect2, varscan2
- XPO6 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as COSV58967278; called by muse, mutect2, varscan2
- YY1AP1 | c.1157A>T p.E386V (on ENST00000295566 / NM_139118.2; = p.E329V on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55121834; called by muse, mutect2, varscan2
- ZNF223 | c.1352G>C p.S451T | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV69691164; called by muse, mutect2, varscan2
- LRP1 | c.1457del p.P486Rfs*67 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- RP1 | c.4918_4932del p.D1640_P1644del | In Frame Del (DEL) | VAF 52/296 reads (18%) | called by mutect2, pindel, varscan2
- SYNE2 | c.953dup p.D319Gfs*5 | Frame Shift Ins (INS) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.784del p.A262Lfs*14 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- ZBTB40 | c.3325dup p.C1109Lfs*30 | Frame Shift Ins (INS) | VAF 26/129 reads (20%) | called by mutect2, pindel, varscan2
- ZFX | c.201_218del p.I68_I73del | In Frame Del (DEL) | VAF 60/196 reads (31%) | called by mutect2, pindel, varscan2
- CENPS | c.354A>G p.S118= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV58364122; called by muse, mutect2, varscan2
- DECR1 | c.33G>A p.L11= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV55169003; called by muse, mutect2
- DNAH5 | c.10803T>A p.P3601= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as COSV54230570; called by muse, mutect2, varscan2
- EPRS1 | c.93C>T p.S31= | Silent (SNP) | VAF 43/279 reads (15%) | catalogued as rs745829078, COSV65099433; called by muse, mutect2, varscan2
- GGA2 | c.843G>T p.R281= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV59168847; called by muse, mutect2, varscan2
- GNB5 | c.39A>C p.S13= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as COSV55899632; called by muse, mutect2, varscan2
- INCENP | c.771C>A p.L257= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV53916538; called by muse, mutect2, varscan2
- KRTAP10-9 | c.306C>A p.P102= | Silent (SNP) | VAF 28/186 reads (15%) | catalogued as COSV59965833; called by muse, mutect2, varscan2
- LMNB2 | c.336A>T p.R112= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV57588481; called by muse, mutect2
- MKNK2 | c.1059C>A p.A353= | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV51732916; called by muse, mutect2, varscan2
- NCAN | c.156G>A p.A52= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs911972409, COSV53052355; called by muse, mutect2, varscan2
- PHYHIPL | c.195A>C p.S65= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV65848790; called by muse, mutect2, varscan2
- PRPF39 | c.615T>C p.S205= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV63276955; called by muse, mutect2, varscan2
- SCN2A | c.1167T>G p.L389= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV51844061; called by muse, mutect2, varscan2
- TACC2 | c.3018G>A p.Q1006= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV57758064; called by muse, mutect2, varscan2
- TOGARAM1 | c.2214G>A p.G738= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV63891280; called by muse, mutect2, varscan2
- XRCC6 | c.1443C>T p.P481= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as rs139850731; called by muse, mutect2
- AL353804.7 | chrX:73851365 G>T | 3'Flank (SNP) | VAF 44/228 reads (19%) | called by muse, mutect2, varscan2
- KLK8 | c.71-29G>A | Intron (SNP) | VAF 21/123 reads (17%) | catalogued as COSV51592285; called by muse, mutect2, varscan2
- SNORD116-7 | n.88T>C | RNA (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
